FM case AD7397 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/9daf327f-e49b-4ac7-996e-e8f79f329480

Female, 55.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the stomach. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
